Somatic mutation profile of tumor specimen PCProject_0093_T2_WES (aliquot PCProject_0093_T2_WES_1) from CMI case PCProject_0093, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 44.6 years (16,279 days).
Specimen PCProject_0093_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb00dd9-0fcb-4339-b5c6-6a98e76a4ff9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0093_BLOOD_BC (Blood Derived Normal), aliquot PCProject_0093_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb1d498-7a8a-46f7-ab3e-4af28287411b

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 3, Splice Site 3, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 34/111 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIM2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs144121944; called by muse, mutect2, varscan2
- DTHD1 | c.1322A>C p.K441T (on ENST00000456874; = p.K276T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV62628644; called by muse, mutect2, varscan2
- DUSP21 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780323745; called by muse, mutect2, varscan2
- KMT2D | c.7118C>T p.S2373F | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1459498988, COSV56409069; called by muse, mutect2, varscan2
- LRP1B | c.13659+1G>T p.X4553_splice | Splice Site (SNP) | VAF 44/137 reads (32%) | catalogued as rs1229502218, COSV67231952, COSV67272133; called by muse, mutect2, varscan2
- MFAP3 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100491647; called by muse, mutect2, varscan2
- NAV2 | c.919C>T p.R307* (on ENST00000396087 / NM_001244963.2; = p.R284* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 69/286 reads (24%) | catalogued as rs755077044, COSV62320721, COSV62328306; called by muse, mutect2, varscan2
- NPFFR2 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs200830127, COSV100440362; called by muse, mutect2, varscan2
- OR2M2 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 34/172 reads (20%) | catalogued as COSV62897670, COSV62898419; called by muse, varscan2
- REEP4 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173419206; called by muse, mutect2, varscan2
- SNTG2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs746789025; called by muse, mutect2, varscan2
- ZFYVE27 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 195/691 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.719); catalogued as rs760410064, COSV104400408, COSV61747218; called by muse, mutect2, varscan2
- ZNF648 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV100374352; called by muse, mutect2, varscan2
- ACVR2B | c.1289_1293del p.V430Gfs*10 | Frame Shift Del (DEL) | VAF 77/388 reads (20%) | called by mutect2, pindel, varscan2
- ADARB1 | c.1990G>A p.A664T (on ENST00000360697 / NM_001346687.2; = p.A624T on NM_001112.4) | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2
- FOCAD | c.3799-1G>T p.X1267_splice | Splice Site (SNP) | VAF 127/377 reads (34%) | called by muse, mutect2, varscan2
- GOLGB1 | c.1611C>G p.S537R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- NANOS1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by mutect2, varscan2
- NSD2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- PLB1 | c.3727-1G>C p.X1243_splice | Splice Site (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- PPP2R2A | c.18_19dup p.G7Efs*12 | Frame Shift Ins (INS) | VAF 36/160 reads (23%) | called by pindel, varscan2
- SCUBE2 | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPTA1 | c.3147G>T p.E1049D | Missense Mutation (SNP) | VAF 126/402 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- THAP1 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- USH2A | c.4163A>G p.N1388S | Missense Mutation (SNP) | VAF 92/329 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BMP5 | c.327C>G p.T109= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- C4orf54 | c.2562C>T p.S854= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as rs1046919271, COSV72766677; called by muse, mutect2, varscan2
- CHST1 | c.423G>A p.P141= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as rs1437246280, COSV57321507, COSV57323443; called by muse, mutect2
- ENPEP | c.162G>A p.A54= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs761812461, COSV54447909; called by muse, mutect2, varscan2
- EYA4 | c.1104G>A p.P368= (on ENST00000531901 / NM_001301013.1; = p.P362= on NM_004100.5) | Silent (SNP) | VAF 101/433 reads (23%) | catalogued as rs763081961, COSV100766317; called by muse, mutect2, varscan2
- IFT52 | c.723G>A p.T241= | Silent (SNP) | VAF 42/225 reads (19%) | catalogued as rs779305915, COSV65974997; called by muse, varscan2
- KCNS1 | c.198C>T p.R66= | Silent (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- SRCIN1 | c.1389C>T p.R463= (on ENST00000621492; = p.R429= on NM_025248.3) | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- TNFSF4 | c.108G>A p.L36= | Silent (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- ZNF730 | c.78G>A p.Q26= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as rs959519851; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390637 C>G | 5'Flank (SNP) | VAF 26/132 reads (20%) | catalogued as rs767276013; called by muse, mutect2
- E2F6 | c.163+12C>G | Intron (SNP) | VAF 36/148 reads (24%) | catalogued as rs373815358; called by muse, mutect2, varscan2
- FBLN5 | c.990-336C>T | Intron (SNP) | VAF 12/194 reads (6%) | catalogued as rs1302973428; called by muse, mutect2
- ZNF154 | c.-26C>T | 5'UTR (SNP) | VAF 10/228 reads (4%) | catalogued as rs1001641586; called by muse, mutect2
